Somatic mutation profile of tumor specimen HCM-BROD-0477-C16-06A (aliquot HCM-BROD-0477-C16-06A-01D-A83U-36) from HCMI case HCM-BROD-0477-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: GX; Age at diagnosis: 68.6 years (25,046 days).
Specimen HCM-BROD-0477-C16-06A: Sample type: Human Tumor Original Cells; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Human Original Cells; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e65e552-9759-46c7-9425-a93c2d4358e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0477-C16-10A (Blood Derived Normal), aliquot HCM-BROD-0477-C16-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d8984c6-ccea-4a28-9535-e2d58cc160c1

The open-access MAF lists 83 somatic variants for this specimen: 70 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Frame Shift Del 15, Frame Shift Ins 14, Silent 11, In Frame Ins 9, In Frame Del 4, Splice Site 2, Nonsense Mutation 1, Intron 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CALHM3 | c.727G>A p.V243M | Missense Mutation (SNP) | VAF 28/968 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV63922186, COSV63922637; called by muse, mutect2
- DNAH9 | c.2312G>A p.R771H | Missense Mutation (SNP) | VAF 46/271 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs747495456, COSV52332686, COSV52354685; called by muse, mutect2, varscan2
- ELAVL4 | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 100/456 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs763451875; called by muse, mutect2, varscan2
- IGKV2-30 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 54/608 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs560652215; called by muse, mutect2
- LACC1 | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.828); catalogued as rs761293228; called by muse, mutect2, varscan2
- PXDN | c.853G>T p.E285* | Nonsense Mutation (SNP) | VAF 25/363 reads (7%) | catalogued as COSV53239055; called by muse, mutect2
- SYT3 | c.1281G>A p.S427= | Splice Region (SNP) | VAF 239/621 reads (38%) | catalogued as rs778913847, COSV58896509; called by muse, mutect2, varscan2
- TAGAP | c.2074C>A p.L692I | Missense Mutation (SNP) | VAF 52/610 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as COSV57851322; called by muse, mutect2
- TMEM87A | c.238A>G p.I80V | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs374342321; called by muse, mutect2, varscan2
- TOP2A | c.2229G>T p.K743N | Missense Mutation (SNP) | VAF 30/262 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV70732591; called by muse, mutect2, varscan2
- TP53 | c.714_715insTG p.N239* | Frame Shift Ins (INS) | VAF 107/439 reads (24%) | catalogued as COSV52663173, COSV52791488; called by mutect2, pindel, varscan2
- ZNF107 | c.2048A>T p.K683M | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV61331563; called by muse, mutect2, varscan2
- ZNF148 | c.2235del p.T746Lfs*10 | Frame Shift Del (DEL) | VAF 155/502 reads (31%) | catalogued as COSV62302097; called by mutect2, pindel, varscan2
- ACTL10 | c.168_200del p.R57_L67del | In Frame Del (DEL) | VAF 202/1038 reads (19%) | called by mutect2, pindel
- ADGRV1 | c.13707_13708del p.N4569Kfs*31 | Frame Shift Del (DEL) | VAF 64/389 reads (16%) | called by mutect2, pindel, varscan2
- ARID1A | c.2227dup p.Q743Pfs*74 | Frame Shift Ins (INS) | VAF 175/714 reads (25%) | called by mutect2, pindel, varscan2
- ASZ1 | c.106-6_130del p.X36_splice | Splice Site (DEL) | VAF 26/121 reads (21%) | called by mutect2, pindel
- B4GALNT3 | c.166_169dup p.R57Tfs*41 | Frame Shift Ins (INS) | VAF 58/498 reads (12%) | called by mutect2, pindel
- BLMH | c.99_100del p.H34Rfs*59 | Frame Shift Del (DEL) | VAF 157/627 reads (25%) | called by mutect2, pindel, varscan2
- CACNA1E | c.1657T>C p.F553L | Missense Mutation (SNP) | VAF 16/484 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); called by muse, mutect2
- CASP10 | c.123_125del p.L42del | In Frame Del (DEL) | VAF 66/424 reads (16%) | called by mutect2, pindel, varscan2
- CDCP1 | c.967C>A p.P323T | Missense Mutation (SNP) | VAF 80/469 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CFAP57 | c.90_91insG p.I31Dfs*46 | Frame Shift Ins (INS) | VAF 73/335 reads (22%) | called by mutect2, pindel, varscan2
- CLIC1 | c.115_130del p.V39Pfs*56 | Frame Shift Del (DEL) | VAF 82/573 reads (14%) | called by mutect2, pindel, varscan2
- CLMP | c.669_671dup p.T224dup | In Frame Ins (INS) | VAF 36/345 reads (10%) | called by mutect2, pindel, varscan2
- CTNND1 | c.867G>T p.M289I | Missense Mutation (SNP) | VAF 101/604 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYP2B6 | c.222dup p.V75Rfs*19 | Frame Shift Ins (INS) | VAF 122/476 reads (26%) | called by mutect2, pindel, varscan2
- DCBLD1 | c.292_293insGTC p.Y98delinsCH | In Frame Ins (INS) | VAF 46/276 reads (17%) | called by mutect2, pindel, varscan2
- DKK1 | c.218dup p.Y74Vfs*5 | Frame Shift Ins (INS) | VAF 61/635 reads (10%) | called by mutect2, pindel, varscan2
- DNASE1L2 | c.596_599del p.M199Sfs*23 | Frame Shift Del (DEL) | VAF 51/398 reads (13%) | called by mutect2, pindel, varscan2
- DYRK1A | c.159_160del p.S54Cfs*6 | Frame Shift Del (DEL) | VAF 122/485 reads (25%) | called by mutect2, pindel, varscan2
- E2F8 | c.2098del p.L700* | Frame Shift Del (DEL) | VAF 154/606 reads (25%) | called by mutect2, pindel, varscan2
- ERI1 | c.914del p.I305Kfs*23 | Frame Shift Del (DEL) | VAF 143/503 reads (28%) | called by mutect2, pindel, varscan2
- ESYT1 | c.1513_1514del p.L505Vfs*43 | Frame Shift Del (DEL) | VAF 86/468 reads (18%) | called by mutect2, pindel*, varscan2*
- FAM83G | c.612_613dup p.I205Tfs*81 | Frame Shift Ins (INS) | VAF 131/549 reads (24%) | called by mutect2, pindel, varscan2
- FAT4 | c.11707A>G p.I3903V | Missense Mutation (SNP) | VAF 99/446 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBXW10 | c.1782_1797del p.L595Afs*10 | Frame Shift Del (DEL) | VAF 49/362 reads (14%) | called by mutect2, pindel, varscan2
- HAUS3 | c.1801C>T p.L601F | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- HSP90AB1 | c.1487del p.N496Tfs*18 | Frame Shift Del (DEL) | VAF 132/576 reads (23%) | called by mutect2, pindel, varscan2
- IHO1 | c.387A>C p.K129N | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2
- JSRP1 | c.597dup p.K200Qfs*58 | Frame Shift Ins (INS) | VAF 249/802 reads (31%) | called by mutect2, pindel, varscan2
- LTBP2 | c.1927A>T p.S643C | Missense Mutation (SNP) | VAF 148/535 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- LTN1 | c.4893_4894insGTA p.T1631_T1632insV | In Frame Ins (INS) | VAF 18/104 reads (17%) | called by mutect2, pindel, varscan2
- LYPLA2 | c.515_530del p.H172Pfs*10 | Frame Shift Del (DEL) | VAF 143/940 reads (15%) | called by mutect2, pindel, varscan2
- METTL17 | c.296dup p.L99Ffs*13 | Frame Shift Ins (INS) | VAF 125/518 reads (24%) | called by mutect2, pindel, varscan2
- MUC16 | c.24460T>A p.S8154T | Missense Mutation (SNP) | VAF 46/542 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.042); called by muse, mutect2
- MVB12A | c.97T>A p.C33S | Missense Mutation (SNP) | VAF 138/410 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- NAMPT | c.1289_1290insTC p.L430Ffs*39 | Frame Shift Ins (INS) | VAF 96/413 reads (23%) | called by mutect2, pindel, varscan2
- NBEAL1 | c.6087del p.Y2029* | Frame Shift Del (DEL) | VAF 24/166 reads (14%) | called by mutect2, pindel, varscan2
- NFKBIA | c.134_135insTCT p.M45delinsIL | In Frame Ins (INS) | VAF 202/758 reads (27%) | called by mutect2, pindel, varscan2
- NNT | c.2606_2621delinsTCAT p.G869_Y874delinsVI | In Frame Del (DEL) | VAF 54/364 reads (15%) | called by pindel, varscan2*
- NRG2 | c.2464_2465insGTA p.Y822delinsCN | In Frame Ins (INS) | VAF 174/759 reads (23%) | called by mutect2, pindel, varscan2
- PCNX1 | c.108_109dup p.Y37Sfs*22 | Frame Shift Ins (INS) | VAF 227/945 reads (24%) | called by mutect2, pindel, varscan2
- PDIA4 | c.1693G>T p.V565L (on ENST00000286091 / NM_001371244.1; = p.V564L on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 135/703 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.022); called by muse, mutect2
- PPP2CB | c.34_35insCAC p.D11_Q12insP | In Frame Ins (INS) | VAF 168/636 reads (26%) | called by mutect2, pindel, varscan2
- PXDN | c.852T>A p.N284K | Missense Mutation (SNP) | VAF 25/353 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.403); called by muse, mutect2
- RAPH1 | c.1489dup p.V497Gfs*29 (on ENST00000319170 / NM_213589.3; = p.V549Gfs*29 on NM_203365.4) | Frame Shift Ins (INS) | VAF 83/369 reads (22%) | called by mutect2, pindel, varscan2
- RFX7 | c.2860A>G p.R954G (on ENST00000559447 / NM_001368074.1; = p.R1051G on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/499 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- RGPD3 | c.1726C>T p.L576F | Missense Mutation (SNP) | VAF 18/420 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); called by muse, mutect2
- RHOB | c.160_162del p.E54del | In Frame Del (DEL) | VAF 258/696 reads (37%) | called by mutect2, pindel, varscan2
- SDE2 | c.1289_1299del p.R430Kfs*5 | Frame Shift Del (DEL) | VAF 83/531 reads (16%) | called by mutect2, pindel, varscan2
- SMAD6 | c.919_922del p.N307Pfs*231 | Frame Shift Del (DEL) | VAF 79/483 reads (16%) | called by mutect2, pindel, varscan2
- SSNA1 | c.53_72del p.X18_splice | Splice Site (DEL) | VAF 77/407 reads (19%) | called by mutect2, pindel, varscan2
- SYMPK | c.2009A>T p.E670V | Missense Mutation (SNP) | VAF 14/474 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); called by muse, mutect2
- TCF20 | c.2409dup p.L804Sfs*27 | Frame Shift Ins (INS) | VAF 149/770 reads (19%) | called by mutect2, pindel, varscan2
- TTC30A | c.1465C>A p.H489N | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- WAC | c.724_726dup p.S243dup | In Frame Ins (INS) | VAF 47/414 reads (11%) | called by mutect2, pindel, varscan2
- WASF2 | c.221_223dup p.R74dup | In Frame Ins (INS) | VAF 110/422 reads (26%) | called by mutect2, pindel, varscan2
- ZNF26 | c.730_731dup p.Q244Hfs*41 | Frame Shift Ins (INS) | VAF 38/449 reads (8%) | called by mutect2, pindel
- ZNF541 | c.3585_3587dup p.V1196dup | In Frame Ins (INS) | VAF 51/514 reads (10%) | called by mutect2, pindel
- ANKS1A | c.2502C>T p.Y834= | Silent (SNP) | VAF 168/616 reads (27%) | catalogued as rs138086834, COSV64459859; called by muse, mutect2
- CCPG1 | c.732A>G p.Q244= | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as rs776883716; called by muse, mutect2, varscan2
- CD200R1 | c.117G>T p.S39= (on ENST00000471858 / NM_170780.3; = p.S62= on NM_138806.4) | Silent (SNP) | VAF 25/231 reads (11%) | called by muse, mutect2, varscan2
- CHL1 | c.1902T>C p.A634= (on ENST00000397491 / NM_001253387.1; = p.A650= on NM_006614.4) | Silent (SNP) | VAF 75/394 reads (19%) | called by muse, mutect2, varscan2
- CKAP5 | c.4938C>T p.L1646= (on ENST00000529230 / NM_001008938.4; = p.L1586= on NM_014756.3) | Silent (SNP) | VAF 111/515 reads (22%) | catalogued as COSV100370686; called by muse, mutect2, varscan2
- MACROH2A2 | c.205A>C p.R69= | Silent (SNP) | VAF 119/612 reads (19%) | called by muse, mutect2, varscan2
- MYLK | c.2850G>A p.Q950= | Silent (SNP) | VAF 194/762 reads (25%) | called by muse, mutect2, varscan2
- PANK2 | c.1389G>T p.L463= (on ENST00000316562 / NM_153638.3; = p.L172= on NM_024960.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/457 reads (4%) | catalogued as COSV57253197; called by muse, mutect2
- PTCHD3 | c.1275A>G p.A425= | Silent (SNP) | VAF 107/673 reads (16%) | called by muse, mutect2, varscan2
- SLC12A2 | c.1197C>T p.S399= | Silent (SNP) | VAF 22/90 reads (24%) | called by muse, varscan2
- SPAG17 | c.6276T>C p.H2092= | Silent (SNP) | VAF 100/409 reads (24%) | catalogued as rs1244737062; called by muse, mutect2, varscan2
- MSH5 | c.1_5dup | 5'UTR (INS) | VAF 123/594 reads (21%) | called by mutect2, pindel, varscan2
- SORBS2 | c.-46+1319_-46+1328del | Intron (DEL) | VAF 102/449 reads (23%) | called by mutect2, pindel, varscan2
